Somatic mutation profile of tumor specimen MP2PRT-PAWAAH-TMP1-A (aliquot MP2PRT-PAWAAH-TMP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PAWAAH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,048 days).
Specimen MP2PRT-PAWAAH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9fab4857-1d74-4eed-b4c5-158299de52ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWAAH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWAAH-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f5f7ef5-68c7-4a26-88dd-50c30f67f8a0

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 11, Silent 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.6644C>A p.S2215Y | Missense Mutation (SNP) | VAF 47/375 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs587777894, COSV63868278, COSV63868313; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.140G>A p.R47K | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1057518425, COSV100909326, COSV64292806; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL27A1 | c.4845G>A p.P1615= | Splice Region (SNP) | VAF 116/358 reads (32%) | catalogued as rs760204476; called by muse, mutect2, varscan2
- EHMT1 | c.334G>T p.D112Y | Missense Mutation (SNP) | VAF 146/431 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV58371181; called by muse, mutect2, varscan2
- GLB1L2 | c.1316C>T p.S439L | Missense Mutation (SNP) | VAF 95/313 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs561326208, COSV100335559; called by muse, mutect2, varscan2
- HNRNPH1 | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 120/313 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as COSV61486998; called by muse, mutect2, varscan2
- KIF18A | c.2003G>A p.R668Q | Missense Mutation (SNP) | VAF 28/306 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.401); catalogued as rs372157089; called by muse, mutect2
- MAGI3 | c.854A>G p.Y285C | Missense Mutation (SNP) | VAF 146/390 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as rs975041594; called by muse, mutect2, varscan2
- SYN3 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 111/349 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141167959; called by muse, mutect2, varscan2
- TTC7A | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 111/302 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as rs1043242155; called by muse, mutect2, varscan2
- H1-6 | c.402G>T p.K134N | Missense Mutation (SNP) | VAF 126/350 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- PCLO | c.8572G>A p.G2858S | Missense Mutation (SNP) | VAF 99/274 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- IQSEC3 | c.1005C>T p.F335= (on ENST00000538872 / NM_001170738.2; = p.F32= on NM_015232.1) | Silent (SNP) | VAF 166/494 reads (34%) | catalogued as rs564712326, COSV58288136; called by muse, mutect2, varscan2
- MUC5B | c.12300C>T p.A4100= | Silent (SNP) | VAF 314/900 reads (35%) | called by muse, mutect2, varscan2
